Somatic mutation profile of tumor specimen TCGA-AK-3447-01A (aliquot TCGA-AK-3447-01A-01D-0966-08) from TCGA case TCGA-AK-3447, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 84.0 years (30,676 days).
Specimen TCGA-AK-3447-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 186c4099-ec39-4bcf-9cc6-3a7d15a53d85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3447-10A (Blood Derived Normal), aliquot TCGA-AK-3447-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f46d76bd-b038-4150-ba88-a036f8f675ec

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 11, Silent 7, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.5596C>T p.H1866Y | Missense Mutation (SNP) | VAF 178/452 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as COSV54026805; called by muse, mutect2, varscan2
- ADAMTS18 | c.3025C>T p.R1009* | Nonsense Mutation (SNP) | VAF 95/209 reads (45%) | catalogued as rs751029682, COSV51402842; called by muse, mutect2, varscan2
- ATRX | c.2304G>C p.K768N | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.327); catalogued as rs1557139920, COSV64874006; ClinVar: uncertain significance; called by muse, mutect2
- DSP | c.1417C>T p.Q473* | Nonsense Mutation (SNP) | VAF 31/148 reads (21%) | catalogued as COSV65791735; called by muse, mutect2, varscan2
- EHBP1L1 | c.2539G>A p.G847R | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs769994697, COSV58572151; called by muse, mutect2, varscan2
- FSTL4 | c.1177+1G>T p.X393_splice | Splice Site (SNP) | VAF 129/361 reads (36%) | catalogued as COSV54767343; called by muse, mutect2, varscan2
- HIVEP3 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1275795270, COSV56012695; called by muse, mutect2
- ITIH4 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 50/123 reads (41%) | catalogued as COSV56572663; called by muse, mutect2, varscan2
- KIAA0232 | c.4174C>T p.R1392* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | catalogued as rs369289730; called by muse, mutect2, varscan2
- LIAS | c.347A>C p.D116A (on ENST00000261434 / NM_001363700.2; = p.D219A on NM_006859.4) | Missense Mutation (SNP) | VAF 124/375 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV54695345; called by muse, mutect2, varscan2
- MED27 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV52599394; called by muse, mutect2
- NAA15 | c.1394G>T p.C465F | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56718543; called by muse, mutect2, varscan2
- NTMT1 | c.265A>G p.M89V | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as rs1448210632, COSV52964667; called by muse, mutect2
- PA2G4 | c.645del p.A216Lfs*42 | Frame Shift Del (DEL) | VAF 51/167 reads (31%) | catalogued as rs34197050; called by mutect2, pindel, varscan2
- RSL1D1 | c.819A>C p.E273D | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as COSV63077585; called by muse, mutect2, varscan2
- SNRNP25 | c.326G>T p.R109I (on ENST00000383018; = p.R100I on NM_024571.4) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV51954402; called by muse, mutect2, varscan2
- TTC16 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs777386178, COSV64777971; called by muse, mutect2, varscan2
- CNOT1 | c.3639+2_3639+3del p.X1213_splice | Splice Site (DEL) | VAF 33/156 reads (21%) | called by pindel, varscan2
- B3GNT3 | c.723C>T p.N241= | Silent (SNP) | VAF 76/202 reads (38%) | catalogued as rs1476091380, COSV57952985; called by muse, mutect2, varscan2
- DNAAF1 | c.1272G>A p.S424= | Silent (SNP) | VAF 63/178 reads (35%) | catalogued as rs772170131, COSV57576413; called by muse, mutect2, varscan2
- ETV3L | c.1071C>A p.P357= | Silent (SNP) | VAF 45/134 reads (34%) | catalogued as COSV71901019; called by muse, mutect2, varscan2
- G6PC3 | c.480G>A p.S160= | Silent (SNP) | VAF 29/297 reads (10%) | catalogued as rs145419406; called by muse, mutect2
- NMRAL1 | c.738C>T p.Y246= | Silent (SNP) | VAF 88/258 reads (34%) | catalogued as rs1042004045, COSV52059537; called by muse, mutect2, varscan2
- NTNG2 | c.549C>T p.R183= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs764857818, COSV62364857; called by muse, mutect2, varscan2
- PKD1 | c.829C>T p.L277= | Silent (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
